Somatic mutation profile of tumor specimen 0DWVFH from CCDI case PBCPJA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 17.2 years (6,276 days).
Specimen 0DWVFH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 831c0c03-c595-419f-903c-ed7ff7e19dc1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWVEI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a98505ab-eb5a-49e4-b6a8-6349463be86a

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Splice Site 2, Nonsense Mutation 1, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.340G>T p.G114C | Missense Mutation (SNP) | VAF 21/212 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as CM044739, CM941372, CM951284, COSV56546928, COSV56549872, COSV56553319; called by muse, mutect2
- COBL | c.3768+1G>A p.X1256_splice | Splice Site (SNP) | VAF 20/508 reads (4%) | called by muse, mutect2
- COL22A1 | c.930G>A p.W310* | Nonsense Mutation (SNP) | VAF 34/1203 reads (3%) | called by muse, mutect2
- EYS | c.1620T>A p.S540R | Missense Mutation (SNP) | VAF 27/943 reads (3%) | SIFT tolerated (0.39); PolyPhen benign (0.218); called by muse, mutect2
- NRAP | c.1671A>C p.K557N (on ENST00000359988 / NM_001322945.2; = p.K522N on NM_006175.4) | Missense Mutation (SNP) | VAF 87/801 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- OPN3 | c.730A>G p.I244V | Missense Mutation (SNP) | VAF 35/1143 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.112); called by muse, mutect2
- TBC1D15 | c.344-2A>C p.X115_splice | Splice Site (SNP) | VAF 107/852 reads (13%) | called by muse, mutect2, varscan2
- THEMIS | c.740G>T p.S247I | Missense Mutation (SNP) | VAF 48/981 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); called by muse, mutect2
- SLC8A3 | c.195G>A p.P65= | Silent (SNP) | VAF 53/463 reads (11%) | catalogued as rs747173075, COSV63518954, COSV63521668; called by muse, mutect2, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 4/74 reads (5%) | called by muse, mutect2
